Gene-level copy-number profile of tumor specimen TCGA-39-5029-01A from TCGA case TCGA-39-5029, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 67.7 years (24,713 days).
Specimen TCGA-39-5029-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.bdd1f8a8-e101-4abd-8e16-5693411852b8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-39-5029-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 825 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/63ed71c9-dcd0-4a58-ad4d-348841497a05

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 485; copy number 2: 16,997; copy number 3: 10,344; copy number 4: 21,221; copy number 5: 3,544; copy number 6: 5,494; copy number 7: 1,260; copy number 8: 262; copy number 10: 97; copy number 11: 2; copy number 12: 11; copy number 14: 3; copy number 21: 54.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-39-5029-01A-01D-1439-01): tumor purity 0.54, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:70,954,708–71,583,989, 1 gene (within-gene range 0–2): FOXP1.
- chr3:71,289,769–71,305,853, 1 gene (within-gene range 0–2): FOXP1-AS1.
- chr9:28,863,626–28,888,955, 2 genes: MIR876, MIR873.
- chr13:27,620,742–28,495,145, 20 genes (within-gene range 0–2): POLR1D, AL136439.1, NPM1P4, GSX1, PLUT, RNU6-73P, PDX1, ATP5F1EP2, LINC00543, CDX2, URAD, RN7SL272P, FLT3, KATNBL1P1, CHCHD2P8, PAN3-AS1, PAN3, EEF1A1P3, RNU6-82P, FLT1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 167 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:2,227,803–2,230,261, 1 gene, copy number 11: AL035693.1.
- chr6:2,341,450–2,341,711, 1 gene, copy number 11: HMGN2P28.
- chr8:37,597,480–43,544,057, 162 genes, copy number 10–21 (broad region; genes not listed).
- chr9:31,371,611–31,506,615, 3 genes, copy number 14: LINC01243, MTATP6P30, MTCO3P30.

Autosomal genes at a single copy (total copy number 1): 482. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
